Surgical pathology report (de-identified scan), TCGA case TCGA-39-5039, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5039-01A (Primary Tumor).

[page 1 of 9]
....

Clinical Diagnosis & History:

RUL mass (+) NSCLC status post bronch meds (-) lymph node.

Specimens Submitted:

- 1: SP: Right middle lobe lung wedge
- 2: SP: Right subscapula soft tissue
- 3: SP: Level seven mediastinal lymph node
- 4: SP: Level seven mediastinal lymph node #3
- 5: SP: Right level 4 mediastinal lymph node
- 6: SP: Right level 4 lymph node #2
- 7: SP: Level seven mediastinal lymph node #2
- 8: SP: Right level four lymph node #3
- 9: SP: Right level four lymph node
- 10: SP: Right upper lobe of lung

AMENDED DIAGNOSIS:

- 1) LUNG, RIGHT MIDDLE LOBE, WEDGE RESECTION:
- LUNG PARENCHYMA WITH FOCAL OSSIFICATION.
- NO CARCINOMA IDENTIFIED.
- 2) SOFT TISSUE, RIGHT SUBCAPULA, EXCISION:
- ELASTOFIBROMA.
- 3) LYMPH NODE, LEVEL VII MEDIASTINUM, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 4) LYMPH NODE #3, LEVEL VII MEDIASTINUM, BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 5) LYMPH NODES, LEVEL IV MEDIASTINUM, BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- 6) LYMPH NODES #2, LEVEL IV, BIOPSY:
- EIGHT BENIGN LYMPH NODES (0/8).
- 7) LYMPH NODES #2, LEVEL VII MEDIASTINUM, BIOPSY:
- ELEVEN LYMPH NODES NEGATIVE FOR CARCINOMA.
- FOLLICULAR LYMPHOMA, GRADE I, PARTIALY INVOLVING ONE LYMPH NODE (SEE NOTE).

** Continued on next page **

[page 2 of 9]
NOTE: THE TUMOR CELLS ARE POSITIVE FOR CD20, BCL-2, BCL-6 AND CD10, WHEREAS NEGATIVE FOR CD23 AND CYCLIN-D1. CD3 AND CD5 MARKS MATURE T-LYMPHOCYTES. A STAIN FOR MIB-1 MARKS APPROXIMATELY 5% OF NEOPLASTIC CELLS. THEREFORE THIS IS A LOW-GRADE LYMPHOMA. [REDACTED] HAS REVIEWED THE SLIDES AND AGREES WITH THE DIAGNOSIS.

- 8) LYMPH NODES #3, RIGHT LEVEL IV, BIOPSY:
- SIXTEEN LYMPH NODES, NEGATIVE FOR CARCINOMA.
- 9) LYMPH NODE, RIGHT LEVEL IV, BIOPSY;
- ONE LYMPH NODE NEGATIVE FOR CARCINOMA.
- 10) LUNG, RIGHT UPPER LOBE, LOBECTOMY:
- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED, OF RIGHT UPPER LOBE. TUMOR CROSSES THE FISSURE INTO THE MIDDLE LOBE.
- THE TUMOR MEASURES 5.5 X 4.3 X 4.0 CM.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE PARENCHYMAL MARGINS AND CHEST WALL MARGINS ARE FREE OF TUMOR.
- THE TUMOR INVADES THROUGH THE PLEURA.
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITY: PARENCHYMAL SCARRING AND EMPHYSEMATOUS CHANGES.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED):
PERIBRONCHIAL: 0/3.

NOTE: IMMUNOSTAINS SHOW THAT THE TUMOR CELLS ARE DIFFUSELY POSITIVE FOR 34Be12 AND A4A (P63), WHEREAS NEGATIVE FOR TTF-1. THIS PATTERN OF IMMUNOREACTIVITY SUPPORTS THE DIAGNOSIS.

Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED]. That report is superseded by the present document.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 3 of 9]
1). The specimen is received fresh for frozen section consultation labeled "right middle lung lobe wedge" and consists of a 1.2 x 0.7 x 0.7 cm portion of lung with a cauterized margin. The cauterized margin is inked black and the specimen is entirely for frozen section consultation.

Summary of sections:
FSC-frozen section control

2). The specimen is received fresh for frozen section consultation labeled "right subscapular soft tissue" and consists of a 4.0 x 3.2 x 2.0 cm fibroadipose soft tissue fragment, the outer surface is inked black and the specimen is sectioned to reveal a fibrotic cut surface. A representative section is submitted for frozen section consultation. Representative sections of the remaining tissue are submitted.

Summary of sections:
FSC-frozen section control
U undesignated

3). The specimen is received fresh for frozen section consultation labeled "level 7 mediastinal lymph node" and consists of a 0.8 x 0.7 x 0.4 cm in red-tan soft tissue fragment, which is entirely submitted for frozen section consultation.

Summary sections:
FSC-frozen section control

4). The specimen is received fresh for frozen section consultation labeled "level 7 mediastinal lymph node #3" and consists of three tan soft tissue fragments measuring 2.8 x 1.6 x 0.7 cm in aggregate, which are entirely submitted for frozen section consultation.

Summary sections:
FSCA-frozen section control
FSCB-frozen section control

5). The specimen is received fresh for frozen section is labeled "right level 4 mediastinal lymph node" and consists of two anthracotic lymph node fragments measuring 1.4 cm and 1.7 cm in greatest dimension. The largest is bisected. The specimen is entirely submitted for frozen section consultation.

Summary of sections:
FSC-frozen section control

** Continued on next page **

[page 4 of 9]
6). The specimen is received fresh for frozen section consultation, labeled "Right level 4 lymph node number two" and consists of a 5 x 3.5 x 1.5 cm piece of fibroadipose tissue, which is sectioned to reveal one partly fatty and anthracotic lymph node measuring 5 x 2.3 x 1.4 cm. The lymph node is representatively sampled for frozen section consultation. Further sectioning through the remaining tissue in the container reveals several additional whole pink-tan lymph nodes ranging in size from 0.2 to 0.5 cm in greatest dimension, which are entirely submitted separately. The remaining lymphoid tissue is entirely submitted for permanent section.

Summary of sections:

FSC-frozen section control

RFL -remainder of frozen lymph node

RLN-remaining whole lymph nodes

7). The specimen is received in formalin, labeled as "level 7 mediastinal lymph node #2", and it consists of multiple possible lymph nodes measuring up to 3.5 cm. The largest lymph node is sectioned. The entire lymph nodes are submitted.

Summary of sections:

LLN -- the largest lymph node

LN -- other lymph nodes

8). The specimen is received in formalin, labeled as "right level 4 lymph node", and it consists of multiple possible lymph nodes measuring up to 2.0 cm. Entirely lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

9). The specimen is received in formalin, labeled as "right level 12 lymph node", and it consists of a possible lymph node measuring 2.2 cm. The specimen is bisected and entirely submitted.

Summary of sections:

BLN -- bisected lymph node

10). The specimen is received in a fresh state, labeled as "right upper lobe of lung", and consists of a right lung upper lobectomy specimen measuring 11.5 x 13 x 5.4 cm weighing 212 g. The portion of middle lobe (4.7 x 2.2 x 0.2 cm, marked by a short stitch) and the portion of the lower lobe (3.5 x 1.5 x 0.3 cm, marked by a long stitch) are adhered to the inferoposterior aspect of the specimen. A 10 cm staple line is identified in the inferior aspect. The specimen is inked in black on the pleura, in blue on the middle lobe margin, in green on the lower lobe margin (after the

** Continued on next page **

[page 5 of 9]
----- Page 5 of 9
removal of the staples), and in red on the staple line (after the removal of the staples). Sectioning reveals a 5.5 X 4.3 X 4.0 cm relatively well-circumscribed firm tan mass in the posterior aspect of the specimen. The adjacent pleura shows fibrous adhesion. The tumor approaches 1.4 cm from the bronchial resection margin, 0.5 cm from the middle lobe margin, 0.7 cm from the lower lobe margin, and 0.3 cm from the staple line. The tumor does not involve the middle lobe or lower lobe parenchyma. The tumor penetrates the anthracotic visceral pleura to invade into the adherent chest wall soft tissue (3.5 x 1.2 x 0.7 cm). Background lung parenchyma shows varying degree of emphysematous change. Multiple peribronchial lymph nodes are identified. The specimen is photographed. TPS is taken. Representative sections are submitted.

Summary of sections:

BM -- bronchial margin
VM -- vascular margin
LL -- lower lobe, perpendicular green margin
ML -- middle lobe, perpendicular blues margin
SL -- staple line, perpendicular red line
TCW -- tumor with attached chest wall
TBR -- tumor with large bronchus
T -- tumor
LN -- lymph nodes
RC -- background lung close to the tumor
RA -- background lung away from the tumor

Summary of Sections:

Part 1: SP: Right middle lobe lung wedge [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		fsc	1

Part 2: SP: Right subscapula soft tissue [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		fsc	1
3		u	3

Part 3: SP: Level seven mediastinal lymph node [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		fsc	1

Part 4: SP: Level seven mediastinal lymph node #3 [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		fsca	1
1		fsob	2

Part 5: SP: Right level 4 mediastinal lymph node [REDACTED] [REDACTED]

** Continued on next page **

[page 6 of 9]
Block	Sect.	Site	PCs
1	fsc		1

Part 6: SP: Right level 4 lymph node #2 [REDACTED]

Block	Sect.	Site	PCs
1	fsc		1
4	rfl		4
1	rln		1

Part 7: SP: Level seven mediastinal lymph node #2 [REDACTED]

Block	Sect.	Site	PCs
4	lln		4
3	ln		3

Part 8: SP: Right level four lymph node #3 [REDACTED]

Block	Sect.	Site	PCs
5	ln		5

Part 9: SP: Right level four lymph node [REDACTED]

Block	Sect.	Site	PCs
2	bln		2

Part 10: SP: Right upper lobe of lung [REDACTED]

Block	Sect.	Site	PCs
1	bm		1
1	ll		1
1	ln		1
3	ml		3
2	ra		2
2	rc		2
3	sl		3
3	t		3
1	tbr		1
2	tcw		2
1	vm		1

Original Diagnosis:

- 1) LUNG, RIGHT MIDDLE LOBE, WEDGE RESECTION:
- LUNG PARENCHYMA WITH FOCAL OSSIFICATION.
- NO CARCINOMA IDENTIFIED.

** Continued on next page **

[page 7 of 9]
PATHOLOGY REPORT

DISEASES NEW

- 2) SOFT TISSUE, RIGHT SUBCAPULA, EXCISION:
- ELASTOFIBROMA.
- 3) LYMPH NODE, LEVEL VII MEDIASTINUM, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 4) LYMPH NODE #3, LEVEL VII MEDIASTINUM, BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 5) LYMPH NODES, LEVEL IV MEDIASTINUM, BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- 6) LYMPH NODES #2, LEVEL IV, BIOPSY:
- EIGHT BENIGN LYMPH NODES (0/8).
- 7) LYMPH NODES #2, LEVEL VII MEDIASTINUM, BIOPSY:
- ELEVEN LYMPH NODES NEGATIVE FOR CARCINOMA.
- FOLLICULAR LYMPHOMA, GRADE I, PARTIALLY INVOLVING ONE LYMPH NODE (SEE NOTE).

NOTE: THE TUMOR CELLS ARE POSITIVE FOR CD20, BCL-2, BCL-6 AND CD10, WHEREAS NEGATIVE FOR CD23 AND CYCLIN-D1. CD3 AND CD5 MARKS MATURE T-LYMPHOCYTES. A STAIN FOR MIB-1 MARKS APPROXIMATELY 5% OF NEOPLASTIC CELLS. THEREFORE THIS IS A LOW-GRADE LYMPHOMA. DR FELDSTEIN HAS REVIEWED THE SLIDES AND AGREES WITH THE DIAGNOSIS.

- 8) LYMPH NODES #3, RIGHT LEVEL IV, BIOPSY:
- SIXTEEN LYMPH NODES, NEGATIVE FOR CARCINOMA.
- 9) LYMPH NODE, RIGHT LEVEL IV, BIOPSY:
- ONE LYMPH NODE NEGATIVE FOR CARCINOMA.
- 10) LUNG, RIGHT UPPER LOBE, LOBECTOMY:
- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED, OF RIGHT UPPER LOBE. TUMOR CROSSES THE FISSURE INTO THE MIDDLE LOBE.
- THE TUMOR MEASURES 5.5 X 4.3 X 4.0 CM.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE PARENCHYMAL MARGINS AND CHEST WALL MARGINS ARE FREE OF TUMOR.
- THE TUMOR INVOLVES THE CHEST WALL.
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITY: PARENCHYMAL SCARRING AND EMPHYSEMATOUS CHANGES.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED):
PERIBRONCHIAL: 0/3.

NOTE: IMMUNOSTAINS SHOW THAT THE TUMOR CELLS ARE DIFFUSELY POSITIVE FOR 34Be12 AND A4A (P63), WHEREAS NEGATIVE FOR TTF-1. THIS PATTERN OF IMMUNOREACTIVITY SUPPORTS THE DIAGNOSIS.

[page 8 of 9]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: RIGHT MIDDLE LOBE LUNG WEDGE
[REDACTED]: REACTIVE CHANGES. NO CARCINOMA SEEN ON FROZEN SECTION. [REDACTED]

PERMANENT DIAGNOSIS: SAME

- 2) FROZEN SECTION DIAGNOSIS: SP: RIGHT SUBSCAPULA SOFT TISSUE (FS)
(MVM): BENIGN. [REDACTED]

PERMANENT DIAGNOSIS: SAME

- 3) FROZEN SECTION DIAGNOSIS: SP: LEVEL SEVEN MEDIASTINAL LYMPH NODE
(FS) (MVM): BENIGN. [REDACTED]

PERMANENT DIAGNOSIS: SAME

- 4A,B) FROZEN SECTION DIAGNOSIS: SP: LEVEL SEVEN MEDIASTINAL
LYMPH NODE #3 [REDACTED]: LYMPH NODE WITH FOCI OF NECROSIS, INFLAMMATION,
AND GIANT CELL REACTION. [REDACTED]

PERMANENT DIAGNOSIS: SAME

- 5) FROZEN SECTION DIAGNOSIS: SP: RIGHT LEVEL 4 MEDIASTINAL LYMPH
NODE [REDACTED] BENIGN. [REDACTED]

PERMANENT DIAGNOSIS: SAME

- 6) FROZEN SECTION DIAGNOSIS: SP: RIGHT LEVEL 4 MEDIASTINAL
LYMPH NODE #2 [REDACTED]: BENIGN ON ONE REPRESENTATIVE SECTION. [REDACTED]

PERMANENT DIAGNOSIS: SAME

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: RIGHT MIDDLE LOBE LUNG WEDGE
[REDACTED]: REACTIVE CHANGES. NO CARCINOMA SEEN ON FROZEN SECTION. [REDACTED]

PERMANENT DIAGNOSIS: SAME

- 2) FROZEN SECTION DIAGNOSIS: SP: RIGHT SUBSCAPULA SOFT TISSUE [REDACTED]
[REDACTED]: BENIGN. [REDACTED]

PERMANENT DIAGNOSIS: SAME

- 3) FROZEN SECTION DIAGNOSIS: SP: LEVEL SEVEN MEDIASTINAL LYMPH NODE
[REDACTED] BENIGN. [REDACTED]

PERMANENT DIAGNOSIS: SAME

- 4A,B) FROZEN SECTION DIAGNOSIS: SP: LEVEL SEVEN MEDIASTINAL
LYMPH NODE #3 [REDACTED]: LYMPH NODE WITH FOCI OF NECROSIS, INFLAMMATION,
AND GIANT CELL REACTION. [REDACTED]

** Continued on next page **

[page 9 of 9]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

Page 9 of 9

PERMANENT DIAGNOSIS: SAME

5) FROZEN SECTION DIAGNOSIS: SP: RIGHT LEVEL 4 MEDIASTINAL LYMPH

NODE [REDACTED] BENIGN. [REDACTED]

PERMANENT DIAGNOSIS: SAME

6) FROZEN SECTION DIAGNOSIS: SP: RIGHT LEVEL 4 MEDIASTINAL

LYMPH NODE #2 [REDACTED]: BENIGN ON ONE REPRESENTATIVE SECTION. [REDACTED]

PERMANENT DIAGNOSIS: SAME

** End of Report **

Source: NCI Genomic Data Commons file 4f5f3f55-c995-4802-8cdf-8332b72dc2aa (TCGA-39-5039.10FD2687-7713-4435-9FCC-0CD6F9A430E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).